Somatic mutation profile of tumor specimen 0DRB5O from CCDI case PBCGHI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,414 days).
Specimen 0DRB5O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2971fe6-1512-4f2c-b766-8958580d021f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRB5Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e40498bf-db5e-4c42-8a48-0899cb38c317

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Intron 6, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.985A>T p.I329F | Missense Mutation (SNP) | VAF 26/650 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as CD095260; called by muse, mutect2
- APCS | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 110/1162 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs760567060; called by muse, mutect2
- ARHGEF18 | c.1321C>T p.R441W (on ENST00000359920 / NM_001130955.2; = p.R337W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/386 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367800762; called by muse, mutect2, varscan2
- CARD14 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746969281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCT5 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 116/654 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs1266138297; called by muse, mutect2, varscan2
- COL4A5 | c.1571G>T p.G524V | Missense Mutation (SNP) | VAF 143/702 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM960364; called by muse, mutect2, varscan2
- COL4A5 | c.4454A>T p.E1485V | Missense Mutation (SNP) | VAF 108/683 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.387); catalogued as COSV100090452; called by muse, mutect2, varscan2
- FOXA3 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs773757045; called by muse, mutect2, varscan2
- H2AP | c.138T>A p.S46R | Missense Mutation (SNP) | VAF 193/610 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV61910811; called by muse, mutect2, varscan2
- OVOL2 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868218784; called by muse, mutect2, varscan2
- TBX18 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 155/529 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63737561; called by muse, mutect2, varscan2
- TRPM2 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1198617003; called by muse, mutect2, varscan2
- AFP | c.1675del p.Q559Kfs*5 | Frame Shift Del (DEL) | VAF 88/508 reads (17%) | called by mutect2, pindel, varscan2
- DIP2B | c.251A>C p.K84T | Missense Mutation (SNP) | VAF 263/1770 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DSCC1 | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 164/555 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ITGA5 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 361/2536 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KMT2A | c.3023C>G p.S1008C | Missense Mutation (SNP) | VAF 29/657 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRCH2 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 169/942 reads (18%) | called by muse, mutect2, varscan2
- MGA | c.4624del p.V1542* | Frame Shift Del (DEL) | VAF 158/448 reads (35%) | called by mutect2, pindel, varscan2
- NUP205 | c.3469G>A p.G1157R | Missense Mutation (SNP) | VAF 176/699 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- RUFY2 | c.1204A>T p.K402* | Nonsense Mutation (SNP) | VAF 113/342 reads (33%) | called by muse, mutect2, varscan2
- SLFN13 | c.137T>A p.V46D | Missense Mutation (SNP) | VAF 101/837 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- THEM5 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 106/538 reads (20%) | called by muse, mutect2, varscan2
- TRIM26 | c.1199A>G p.E400G | Missense Mutation (SNP) | VAF 44/848 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- ZNF777 | c.2105G>C p.S702T | Missense Mutation (SNP) | VAF 75/274 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ADAMTS1 | c.1731A>G p.G577= | Silent (SNP) | VAF 180/556 reads (32%) | called by muse, mutect2, varscan2
- BTAF1 | c.2664A>G p.E888= | Silent (SNP) | VAF 44/578 reads (8%) | catalogued as rs1001038841; called by muse, mutect2
- ESPL1 | c.1818C>A p.I606= | Silent (SNP) | VAF 103/982 reads (10%) | called by muse, mutect2, varscan2
- FCRL6 | c.156C>T p.F52= | Silent (SNP) | VAF 59/740 reads (8%) | called by muse, mutect2
- HSPA6 | c.1884C>G p.A628= | Silent (SNP) | VAF 33/876 reads (4%) | called by muse, mutect2
- MED13 | c.6453C>T p.D2151= | Silent (SNP) | VAF 183/932 reads (20%) | called by muse, mutect2, varscan2
- OR2T10 | c.426C>T p.L142= | Silent (SNP) | VAF 58/600 reads (10%) | catalogued as rs1347272129, COSV57896191, COSV57896291, COSV57896464; called by muse, mutect2
- PIP4K2C | c.1059C>A p.V353= | Silent (SNP) | VAF 128/4720 reads (3%) | called by muse, mutect2
- EIF4A2 | c.76-12dup | Intron (INS) | VAF 179/654 reads (27%) | catalogued as rs766380521; called by mutect2, pindel, varscan2
- KATNAL2 | c.1211+6976C>T | Intron (SNP) | VAF 176/961 reads (18%) | called by muse, mutect2, varscan2
- LIM2 | c.175+29C>T | Intron (SNP) | VAF 68/256 reads (27%) | catalogued as rs533314455, COSV99702174; called by muse, mutect2, varscan2
- LINC00378 | n.378+33204G>A | Intron (SNP) | VAF 27/79 reads (34%) | catalogued as rs535922681; called by muse, mutect2, varscan2
- MEAF6 | c.*354G>A | 3'UTR (SNP) | VAF 109/349 reads (31%) | catalogued as COSV56163160; called by muse, mutect2, varscan2
- NACA | c.70+4218C>T | Intron (SNP) | VAF 166/3037 reads (5%) | catalogued as rs749793112; called by muse, mutect2
- OLFML1 | c.-6T>C | 5'UTR (SNP) | VAF 88/544 reads (16%) | called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55814242; called by muse, mutect2
